Somatic mutation profile of tumor specimen 0DKPXD from CCDI case PBBXNB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.2 years (72 days).
Specimen 0DKPXD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bc9c953-d9e4-423d-84c0-af7e7690abcd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKPW9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b88baccc-6a0e-4ee3-8c34-82933ac44054

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FRMD4A | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 53/538 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.738); catalogued as rs369326023; called by muse, mutect2
- KRT32 | c.734T>C p.L245P | Missense Mutation (SNP) | VAF 157/649 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs774996977; called by muse, mutect2, varscan2
- OR5W2 | c.295C>A p.L99M | Missense Mutation (SNP) | VAF 32/688 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.215); catalogued as COSV60615680; called by muse, mutect2
- TXNDC8 | c.126C>G p.F42L | Missense Mutation (SNP) | VAF 34/474 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as rs1412573276; called by muse, mutect2
- GTPBP4 | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 13/490 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
